Gene-level copy-number profile of tumor specimen TCGA-OR-A5J1-01A from TCGA case TCGA-OR-A5J1, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 58.9 years (21,496 days).
Specimen TCGA-OR-A5J1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ACC.1387b6c7-48fe-4961-86a7-0bdcbd3fef92.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-OR-A5J1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3082226e-af71-4155-bf14-83db120c891c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,072; copy number 2: 52,637; copy number 3: 1,532; copy number 4: 307; copy number 5: 111; copy number 6: 99; copy number 7: 10; copy number 11: 12; copy number 12: 8; copy number 14: 5; copy number 15: 14; copy number 16: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-OR-A5J1-01A-11D-A29H-01): tumor purity 0.9, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 263 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:2,712,591–3,181,487, 8 genes, copy number 12: LSINCT5, AC091891.1, IRX2, C5orf38, AC116359.1, AC094105.1, AC094105.2, LINC01377.
- chr5:4,012,708–4,147,429, 3 genes, copy number 5: AC025773.1, AC025187.1, LINC02063.
- chr5:5,688,805–5,694,742, 1 gene, copy number 6 (within-gene range 1–6): AC026736.1.
- chr5:6,289,857–6,496,723, 5 genes, copy number 14: HMGB3P3, LINC02145, MED10, AC093307.1, UBE2QL1.
- chr5:35,429,064–35,827,018, 4 genes, copy number 16 (within-gene range 1–16): U3, SPEF2, RNU7-130P, AC137810.1.
- chr5:36,035,021–36,876,700, 18 genes, copy number 7–15 (within-gene range 2–15): UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3, AC026741.1, NIPBL-DT.
- chr5:38,937,920–41,587,787, 34 genes, copy number 5–15: RICTOR, AIG1P1, AC008964.1, FYB1, GOLGA5P1, C9, DAB2, LINC02104, CCDC11P1, INTS6P1, GCSHP1, LINC00603, KRT18P56, LINC00604, RNU1-150P, AC108105.1, AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1.
- chr16:87,881,546–88,100,985, 7 genes, copy number 6: CA5A, AC133539.1, AC127455.1, BANP, AC134312.4, AC134312.3, AC134312.1.
- chr19:39,236,433–40,808,418, 93 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr19:43,460,787–44,954,007, 90 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,714. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
